Surgical pathology report (de-identified scan), TCGA case TCGA-2F-A9KW, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Erasmus MC, specimen TCGA-2F-A9KW-01A (Primary Tumor).

Pathology report

Date of tumor procurement

Date of report

Histologic diagnosis

High grade muscle invasive urothelial cell carcinoma. Also carcinoma in situ (CIS). pT3bG3 N0

Anatomic site and laterality

Right bladder wall

Tumor size

1.2cm diameter

Lymph node status

In total 16 lymph nodes all without tumor localization

ICD-O-3
Carcinoma, urothelial
8/20/13
Site Bladder wall NOS
C67.9
JCS 3/7/14

Source: NCI Genomic Data Commons file d2df2b7a-8eab-4715-8284-10a852896179 (TCGA-2F-A9KW.C4DACE91-4ED5-4259-9C31-F1C118E40AAE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).